Gene-level copy-number profile of tumor specimen TCGA-EI-7004-01A from TCGA case TCGA-EI-7004, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectosigmoid junction; Age at diagnosis: 37.1 years (13,566 days).
Specimen TCGA-EI-7004-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.516f1003-cbbb-4fb6-b06e-496b54617bdf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EI-7004-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0fe261df-ddf2-4706-b8d5-1386e2ec4dea

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 2: 13,126; copy number 3: 504; copy number 4: 35,165; copy number 5: 1,400; copy number 6: 7,577; copy number 7: 915; copy number 8: 283; copy number 9: 777; copy number 11: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EI-7004-01A-11D-1923-01): tumor purity 0.49, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:2,935,353–4,994,972, 1 gene (within-gene range 0–2): CSMD1.
- chr8:4,317,388–5,142,707, 8 genes: AC027251.1, AC010941.1, AC022068.1, PAICSP4, AC019176.1, AC019176.2, SNORA70, RN7SL318P.
- chr11:57,753,243–58,318,375, 25 genes (within-gene range 0–2): CTNND1, OR5BA1P, AP003484.1, OR5AZ1P, OR5BD1P, CYCSP26, OR9Q1, RNU6-899P, OR6Q1, VN2R9P, AP004247.2, AP004247.1, OR9L1P, OR9I3P, OR9I1, OR9I2P, OR5BL1P, OR9Q2, OR1S2, OR1S1, OR10Q1, EIF4A2P3, OR10W1, OR10Q2P, OR5BC1P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 809 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:69,598,296–87,220,587, 264 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr7:88,759,700–90,513,402, 18 genes, copy number 9: ZNF804B, TEX47, AC002383.1, RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1.
- chr7:90,469,639–90,632,568, 3 genes, copy number 9: AC002456.2, AC002456.1, TVP23CP1.
- chr7:100,867,387–114,693,772, 229 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr9:131,125,586–131,234,663, 1 gene, copy number 9 (within-gene range 6–9): NUP214.
- chr9:131,132,852–138,203,325, 262 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr13:27,792,483–29,595,688, 32 genes, copy number 11: GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1, PAN3, EEF1A1P3, RNU6-82P, FLT1, AL139005.1, EIF4A1P7, Y_RNA, POMP, SLC46A3, RNU6-53P, CYP51A1P2, AL359741.1, POM121L13P, MTUS2, MTUS2-AS2, GAPDHP69, AL596092.1, MTUS2-AS1, SLC7A1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
